Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5461, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5461-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT

TCGA-CZ-5461

***** Addended Report *****

PATHOLOGIC DIAGNOSIS:

RIGHT KIDNEY, NEPHRECTOMY:

RENAL CELL CARCINOMA, CLEAR CELL TYPE (6.4 cm), Fuhrman nuclear grade IV of IV, with FOCAL SARCOMATOID DIFFERENTIATION and focal papillary features.

The tumor is confined to the kidney.

No vascular invasion identified.

The vascular, ureteric, and soft tissue margins are negative for tumor. Non-neoplastic kidney will be evaluated by the Renal Pathology Service and reported in an addendum.

AJCC Classification (6th Edition): T1b NX MX.

NOTE: This case was also reviewed by Dr. [REDACTED] Pathology Service, who concurs.

CLINICAL DATA:

History: A [REDACTED] with metastatic RCC.

Operation: None given.

Operative Findings: None given.

Clinical Diagnosis: None given.

TISSUE SUBMITTED:

Right kidney.

GROSS DESCRIPTION:

The specimen is submitted fresh, in one part, labeled with the patient's name, unit number, and "#1. Right kidney", and consists of 451.5-gram right nephrectomy measuring 17.0 x 6.3 x 5.0 cm in overall dimension with 0.8 cm in length x 1.1 cm in diameter vein, 1.6 cm in length x 0.5 cm in diameter artery, and 4.2 cm in length x 0.4 cm in diameter ureter. Resection margin is inked black. There is a 6.2 x 5.3 x 4.5 cm tan/white to tan/yellow focally cystic focally hemorrhagic partially encapsulated mass at the inferior pole of the kidney, which is abutting kidney capsule (less than 0.1 cm away from in inked margin), 4.2 cm away from the vein margin, 5.6 cm away from the artery margin, and 7.8 cm away from the ureteral margin. Representative sections of the mass are submitted for cytogenetics and tissue bank for special studies. Representative sections of the normal kidney parenchyma are submitted for electron microscopy, immunofluorescence and tissue bank for special studies. No adrenal gland is grossly identified. Mass does not appear to grossly invade perirenal fat.

Micro A1: Ureter, artery and vein margin, 3 frags, [REDACTED]

Micro A2: T1, 2 frags, [REDACTED]

Micro A4: T2, 2 frags, [REDACTED]

Micro A3: T3, 1 frag, [REDACTED]

Micro A4: Tumor, 1 frag, [REDACTED]

Micro A5: Tumor in relationship to the nearest vascular structure, renal artery, 1 frag, [REDACTED]

Micro A6: Tumor in relationship to kidney parenchyma, 1 frag, [REDACTED]

Micro A7 and A8: Tumor in relationship to the renal capsule, 2 frags, [REDACTED]

Micro A9 and A10: Tumor in relationship to perirenal fat, 2 frags, [REDACTED]

Micro A11: Tumor in relationship to renal sinus, 1 frag, [REDACTED]

Micro A12: Normal renal parenchyma, 1 frag, [REDACTED]

[page 2 of 2]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT
Cytogeneticist: [REDACTED]

Report Status: Final

TCGA-CZ-5461

KARYOTYPE: T1: 46,XY,del(3)(p1?2p1?4) [5] T2: 46,XY,del(3)(p1?2p1?4) [5]

METAPHASES COUNTED: 10 ANALYZED: 10 SCORED: BANDING: GTG

INTERPRETATION:

Three different specimens were received. An interstitial deletion was seen in specimen labeled T1 and T2, a characteristic finding in renal cell carcinoma, clear cell type.

No metaphases were available from specimen T3, therefore the cytogenetic analysis could not be performed.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC. Tumors 1-3

[REDACTED]

Source: NCI Genomic Data Commons file 56510bfd-b5ec-456c-958f-e4107419911b (TCGA-CZ-5461.1AD395CE-33B0-478F-BF99-47CD60319C94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).